Somatic mutation profile of tumor specimen TCGA-EJ-7325-01B (aliquot TCGA-EJ-7325-01B-11D-A32B-08) from TCGA case TCGA-EJ-7325, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 63.0 years (23,029 days).
Specimen TCGA-EJ-7325-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d8fc4fd0-5e53-4b3b-909b-edb2a11923aa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-7325-10A (Blood Derived Normal), aliquot TCGA-EJ-7325-10A-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/03c7ab9e-d98c-4f02-8d88-fbe1fb390b10

The open-access MAF lists 25 somatic variants for this specimen: 17 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 12, Silent 8, Frame Shift Del 2, Nonsense Mutation 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4616C>G p.S1539* | Nonsense Mutation (SNP) | VAF 38/56 reads (68%) | catalogued as CM106377, CM970093, COSV57338178, COSV57338685, COSV57338819; called by muse, mutect2, varscan2
- ARHGAP32 | c.2258A>G p.N753S (on ENST00000310343 / NM_001378025.1; = p.N404S on NM_014715.4) | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.189); catalogued as COSV100089474; called by muse, mutect2, varscan2
- CLCN1 | c.1266A>C p.E422D | Missense Mutation (SNP) | VAF 80/188 reads (43%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.985); catalogued as COSV100578584, COSV58375087; called by muse, mutect2, varscan2
- EIF3C | c.887A>G p.N296S | Missense Mutation (SNP) | VAF 161/803 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.041); catalogued as rs369740611; called by muse, mutect2, varscan2
- FAM83B | c.2657C>A p.A886D | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.621); catalogued as COSV100175062, COSV60920900; called by muse, mutect2, varscan2
- FANCD2 | c.2173G>A p.V725M | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.604); catalogued as COSV99812587; called by muse, mutect2, varscan2
- FLVCR1 | c.647T>G p.F216C | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.856); catalogued as COSV100757939; called by muse, mutect2, varscan2
- ITGA2B | c.1292G>T p.R431M | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV52232129; called by muse, mutect2, varscan2
- KPRP | c.796C>T p.P266S | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.173); catalogued as COSV100908817; called by muse, mutect2, varscan2
- KRTAP1-3 | c.399C>A p.C133* | Nonsense Mutation (SNP) | VAF 11/35 reads (31%) | catalogued as COSV100727502; called by muse, mutect2, varscan2
- MMP17 | c.1162G>A p.V388M | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs374841041; called by muse, mutect2, varscan2
- PKD1 | c.12445-8G>A | Splice Region (SNP) | VAF 28/79 reads (35%) | catalogued as rs776530070, COSV51926485; called by muse, mutect2, varscan2
- PLXNA1 | c.4981G>A p.D1661N | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs770125385, COSV99304209; called by muse, mutect2, varscan2
- TFB1M | c.212G>C p.R71T | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100905255; called by muse, mutect2, varscan2
- TRPA1 | c.1351C>A p.H451N | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51576772; called by muse, mutect2, varscan2
- DOCK2 | c.2526del p.I842Mfs*24 | Frame Shift Del (DEL) | VAF 53/171 reads (31%) | called by mutect2, pindel, varscan2
- SMG7 | c.1941_1944del p.P648Ffs*81 | Frame Shift Del (DEL) | VAF 33/102 reads (32%) | called by mutect2, pindel, varscan2
- DAO | c.564G>A p.A188= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs370764819; called by muse, mutect2, varscan2
- FAM83D | c.1302G>A p.T434= | Silent (SNP) | VAF 29/69 reads (42%) | catalogued as rs758455015, COSV54156698; called by muse, mutect2, varscan2
- GGPS1 | c.115C>T p.L39= | Silent (SNP) | VAF 24/102 reads (24%) | catalogued as COSV99270628; called by muse, mutect2, varscan2
- NFASC | c.627C>T p.T209= (on ENST00000339876 / NM_001378329.1; = p.T203= on NM_015090.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/90 reads (12%) | catalogued as rs374961734; called by muse, mutect2, varscan2
- PRKN | c.519G>A p.T173= | Silent (SNP) | VAF 24/72 reads (33%) | catalogued as rs757533563, COSV58209895; called by muse, mutect2, varscan2
- RYR2 | c.10851C>T p.V3617= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV100773116; called by muse, mutect2, varscan2
- SLITRK5 | c.1038T>C p.S346= | Silent (SNP) | VAF 48/113 reads (42%) | catalogued as COSV100280697; called by muse, mutect2, varscan2
- ZFPM2 | c.1365G>A p.E455= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as COSV101023625; called by muse, mutect2, varscan2
